Gene-level copy-number profile of tumor specimen TCGA-V5-AASW-01A from TCGA case TCGA-V5-AASW, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G3; Age at diagnosis: 72.7 years (26,571 days).
Specimen TCGA-V5-AASW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.7d33da74-7bef-4020-8a6a-18a292551555.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-V5-AASW-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/93977824-c0a5-4f04-99a7-af8c2dae3ac2

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 1,055; copy number 2: 24,641; copy number 3: 22,483; copy number 4: 10,843; copy number 5: 146; copy number 6: 133; copy number 7: 296; copy number 8: 102; copy number 9: 7; copy number 11: 1; copy number 22: 85.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-V5-AASW-01A-11D-A402-01): tumor purity 0.73, ploidy 2.75, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:8,858,127–8,963,077, 2 genes: PTPRD-AS1, AL596451.1.
- chr9:21,524,307–22,029,594, 12 genes (within-gene range 0–1): SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes: AL449423.1, CDKN2B, UBA52P6.
- chr9:27,325,209–27,529,814, 3 genes (within-gene range 0–2): MOB3B, AL163192.1, AL451123.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 491 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:165,122,713–176,114,537, 152 genes, copy number 7 (broad region; genes not listed).
- chr3:177,010,719–177,349,166, 8 genes, copy number 7: MTND5P15, TBL1XR1, TBL1XR1-AS1, Y_RNA, RNU6-681P, LINC00501, ASS1P7, AC117465.1.
- chr3:177,503,303–177,503,552, 1 gene, copy number 7: RN7SKP52.
- chr3:188,941,715–196,082,096, 135 genes, copy number 7 (broad region; genes not listed).
- chr5:443,175–667,168, 8 genes, copy number 9–11 (within-gene range 3–11): EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72.
- chr17:38,800,441–41,836,260, 187 genes, copy number 8–22 (within-gene range 4–22) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,055. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
